Surgical pathology report (de-identified scan), TCGA case TCGA-CW-6090, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-CW-6090-01A (Primary Tumor).

Surgical Pathology

TCGA-CW-6090

TISSUE DESCRIPTION:

Right kidney (300 grams, 13.5 x 7.0 x 7.0 cm with 8.5 cm of ureter)
and tissue from left kidney (aggregating 5.5 x 2.2 x 1.5 cm)

DIAGNOSIS:

Kidney, right, radical nephrectomy: Grade 3 of (4) renal cell carcinoma, clear cell type, forms a 6 x 5.8 x 5.0 cm mass located in the upper pole. The tumor is confined to the kidney. The renal vein is grossly free of tumor. The tumor does not involve the collecting system. Coagulative tumor necrosis is absent. Sarcomatoid differentiation is absent. The surgical margins are negative for tumor. No renal hilar lymph nodes are identified. The adrenal gland is present and is unremarkable.

Kidney, left, partial nephrectomy: Grade 1 of (4) cystic renal cell carcinoma, clear cell type, forms a 1.6 x 1.5 x 1.0 cm mass located in the mid pole. The tumor is confined to the kidney. Coagulative tumor necrosis is absent. Sarcomatoid differentiation is absent. The surgical margins are negative. No renal hilar lymph nodes are identified.).

Source: NCI Genomic Data Commons file 02ea31ee-393f-41f2-b313-e12c35ac1c22 (TCGA-CW-6090.869323AB-5D34-4EEE-9A83-264D024450E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).